Gene-level copy-number profile of tumor specimen TCGA-OR-A5LI-01A from TCGA case TCGA-OR-A5LI, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 42.5 years (15,536 days).
Specimen TCGA-OR-A5LI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.f2437da7-9419-483b-9357-1f1125b639c3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5LI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5c14111b-01a9-43a8-867b-07d21c07d954

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 785; copy number 2: 4,855; copy number 3: 22,011; copy number 4: 29,070; copy number 5: 2,700; copy number 6: 362; copy number 7: 3; copy number 8: 14; copy number 10: 5; copy number 12: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5LI-01A-11D-A309-01): tumor purity 0.9, ploidy 3.51, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:28,883,572–29,061,844, 4 genes (within-gene range 0–1): ZNRF3, ZNRF3-IT1, ZNRF3-AS1, C22orf31.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:111,839,828–111,839,934, 1 gene, copy number 10: RNU6-1013P.
- chr12:124,637,999–124,882,668, 4 genes, copy number 10 (within-gene range 4–10): AC073592.4, AC073593.1, SCARB1, AC073593.2.
- chr19:29,811,991–29,901,869, 3 genes, copy number 12: CCNE1, AC008798.2, AC008798.1.

Autosomal genes at a single copy (total copy number 1): 785. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
